Somatic mutation profile of tumor specimen TCGA-FG-A70Y-01A (aliquot TCGA-FG-A70Y-01A-12D-A34J-08) from TCGA case TCGA-FG-A70Y, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 20.3 years (7,421 days).
Specimen TCGA-FG-A70Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d968f8b-9d34-4a3c-b486-0ddc29be260b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A70Y-10B (Blood Derived Normal), aliquot TCGA-FG-A70Y-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/099e3a2e-0690-4d14-9464-69ad4afbc919

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 5'Flank 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 52/153 reads (34%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/103 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.806_811del p.S269_E271delinsK | In Frame Del (DEL) | VAF 10/23 reads (43%) | hotspot (GDC flag); called by mutect2, varscan2
- AGTR2 | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100903626; called by muse, mutect2, varscan2
- CARD6 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99621237; called by muse, mutect2, varscan2
- CDC7 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319915; called by muse, mutect2
- KIF2B | c.347T>G p.V116G | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV99276126; called by muse, mutect2, varscan2
- MAP7D3 | c.1539T>C p.T513= | Splice Region (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100286652; called by muse, mutect2
- NT5C1A | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.359); catalogued as rs758863154, COSV99348652; called by muse, mutect2, varscan2
- OR10K1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs760475592, COSV56871350; called by muse, mutect2, varscan2
- SCN11A | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs777323474, COSV56567930, COSV56568066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3PXD2A | c.2548G>A p.A850T (on ENST00000369774 / NM_001365079.1; = p.A822T on NM_014631.2) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.5); catalogued as rs764554398, COSV60120511; called by muse, mutect2, varscan2
- SLC25A47 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs144140477; called by muse, mutect2, varscan2
- TAPT1 | c.259A>C p.N87H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101301501; called by muse, mutect2, varscan2
- TTC1 | c.112A>G p.N38D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99180660; called by muse, mutect2
- MYLK | c.4269G>A p.T1423= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs574785619, COSV100659552; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R3A | c.2163T>C p.I721= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV99494115; called by muse, mutect2, varscan2
- SIGIRR | c.180C>T p.G60= | Silent (SNP) | VAF 83/213 reads (39%) | catalogued as COSV100230279; called by muse, mutect2, varscan2
- SLC2A9 | chr4:10025942 C>T | 5'Flank (SNP) | VAF 28/119 reads (24%) | catalogued as COSV53320032; called by muse, mutect2, varscan2
